Surgical pathology report (de-identified scan), TCGA case TCGA-CR-7388, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site Vanderbilt University, specimen TCGA-CR-7388-01A (Primary Tumor).

SURGICAL PATHOLOGY REPORT

Accession Number: [REDACTED]

Final Report

DIAGNOSIS:

1) LARYNX, SUPRAGLOTTIC, BIOPSY: INVASIVE MODERATELY DIFFERENTIATED SQUAMOUS CELL CARCINOMA.

CLINICAL DATA

Clinical Features/Dx: unspecified

Operator: [REDACTED]

Operation: unspecified

Operative Findings: unspecified

Operative Diagnosis: unspecified

Tissue Submitted: 1) supraglottic larynx

GROSS DESCRIPTION:

1) SOURCE: Supraglottic Larynx

Received fresh labeled, "supraglottic larynx," is a 1.0 x 1.0 x 0.3 cm aggregate of pink-tan tissue. The specimen is filtered and submitted in total.

Summary of sections: 1A, m/1.

Dictated by [REDACTED]

[REDACTED]
Slides and report reviewed by Attending Pathologist.

SNOMED: T-24100,M-80703,

[REDACTED]

[REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file cba659cf-981c-4ef9-bbf3-a7e89cd2bd93 (TCGA-CR-7388.FDF7BE62-B093-4D5B-ACCD-EDA6EC84D4FF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).